Surgical pathology report (de-identified scan), TCGA case TCGA-FC-A8O0, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Asterand, specimen TCGA-FC-A8O0-01A (Primary Tumor).

[page 1 of 2]
TSS Patient ID:

Surgical Date:

Gross Description: 1.Group of 6 (six) lymph nodes of maximum 0.5 cm in diameter, with reactive aspect and sclerolipomatous dystrophy.

2. Connective-adipose tissue which includes 6 (six) lymph nodes of maximum 0.8 cm in diameter, with reactive aspect and sinus histiocytosis.

3. Piece of radical prostatectomy (60g; 6/4.5/3 cm with smooth contour, nodular aspect on section, grey-yellow coloration.

Histopathological aspect of multifocal acinar adenocarcinoma of the prostate with distinct/ fused micro-glandular pattern; Gleason score 6 (3+3).

The tumoral proliferation spreads inside the prostate with perineural and perivascular infiltration of the peripheral bundles, without invasion of the seminal vesicles; stpT3.

Microscopic Description: see above

Diagnosis Details: CONCLUSION:

Adenocarcinoma of the prostate, Gleason score 6, stpT3, pN0, Mx (stage III) (RO).

Comments:

Formatted Path Reports: PROSTATE TISSUE CHECKLIST

Specimen type: Prostatectomy and lymph node dissection

Tumor size: 6 x 4.5 x 3 cm

Histologic type: Acinar cell adenocarcinoma

Gleason's score: 3 + 3 = 6/10

Focality: Not specified

Laterality: Bilateral

Extraprostatic extension: Present

Lymph nodes: 0/12 positive for metastasis (Right and left external obturator and internal 0/12)

Lymphatic invasion: Not specified

ICD-O-3

Adenocarcinoma, acinar 8140/3

Site: Prostate NOS C61.9

QW 11/26/13

[page 2 of 2]
Venous invasion: Not specified

Seminal vesicle invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: Not specified

Comments: None

Agonist Discrepancy		✓
For Malignancy History		✓

Source: NCI Genomic Data Commons file 1f4f6870-1cae-4341-882c-68a1a32d11cc (TCGA-FC-A8O0.4DC18F34-9319-45E5-8ECA-D86E9CD81EE6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).